Somatic mutation profile of tumor specimen 0DJ8KS from CCDI case PBBWJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.0 years (4,766 days).
Specimen 0DJ8KS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0daaaf5d-6318-4cd2-ba78-e3a451618a66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ8JM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b41f78ec-f0a0-42d7-a776-2a423eb4c733

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Splice Site 1, Silent 1, 3'Flank 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRRM1 | c.1892C>G p.P631R | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.052); catalogued as rs753560125; called by muse, mutect2
- WWC3 | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 25/757 reads (3%) | catalogued as rs1196161286, COSV66504180; called by muse, mutect2
- GAD1 | c.867+1G>T p.X289_splice | Splice Site (SNP) | VAF 132/355 reads (37%) | called by muse, mutect2, varscan2
- SPATA13 | c.1830C>G p.P610= | Silent (SNP) | VAF 116/893 reads (13%) | called by muse, mutect2, varscan2
- HYKK | chr15:78537353 A>G | 3'Flank (SNP) | VAF 36/306 reads (12%) | called by muse, mutect2, varscan2
- NRTN | c.*16C>T | 3'UTR (SNP) | VAF 150/420 reads (36%) | catalogued as rs1305248148; called by muse, mutect2, varscan2
